Somatic mutation profile of tumor specimen TCGA-98-7454-01A (aliquot TCGA-98-7454-01A-11D-2042-08) from TCGA case TCGA-98-7454, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.4 years (26,827 days).
Specimen TCGA-98-7454-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2477dfef-7f96-4629-84a8-a462ec8b3452.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-7454-10A (Blood Derived Normal), aliquot TCGA-98-7454-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/933ca5c2-21aa-4c54-867d-98bd06582cb5

The open-access MAF lists 204 somatic variants for this specimen: 156 protein-altering or splice-affecting, 41 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 41, Nonsense Mutation 11, Frame Shift Del 4, Intron 4, 3'UTR 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.3406A>T p.T1136S | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100229196; called by muse, mutect2
- ADAMTS12 | c.1913G>T p.R638L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100711386; called by muse, mutect2, varscan2
- ADCY8 | c.989G>T p.C330F | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99653257; called by muse, mutect2, varscan2
- ADGRB2 | c.3739G>T p.V1247L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99926615; called by muse, mutect2, varscan2
- AFDN | c.3755A>G p.Y1252C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV100653238; called by muse, mutect2, varscan2
- ANK2 | c.6587G>T p.G2196V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as rs969552950, COSV100002889; called by muse, mutect2, varscan2
- ANKRD13B | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV101198930; called by muse, mutect2, varscan2
- ANO4 | c.926G>C p.R309P (on ENST00000392977 / NM_001286615.2; = p.R274P on NM_178826.4) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as COSV100152812, COSV100153324; called by muse, mutect2, varscan2
- ARID1B | c.2183G>C p.G728A | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99270608; called by muse, mutect2, varscan2
- ARL5B | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV101040353; called by mutect2, varscan2
- ATP13A5 | c.3089G>C p.G1030A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV100665430; called by muse, mutect2, varscan2
- BCLAF3 | c.2050G>T p.G684C (on ENST00000379682 / NM_001367774.1; = p.G655C on NM_198279.3) | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503344; called by muse, mutect2
- CAPN6 | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 56/391 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV100136959; called by muse, mutect2, varscan2
- CBFA2T3 | c.165G>C p.R55S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1192506119, COSV99242121; called by muse, mutect2, varscan2
- CCDC186 | c.1963C>G p.L655V | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100991127; called by muse, mutect2, varscan2
- CCDC62 | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99457452; called by muse, mutect2, varscan2
- CD101 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV99869904; called by muse, mutect2, varscan2
- CDC123 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as COSV55396996, COSV99827055; called by muse, mutect2, varscan2
- CDC37L1 | c.686T>A p.M229K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV101116619; called by muse, mutect2, varscan2
- CDC42EP4 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV100231901; called by muse, mutect2, varscan2
- CDKL5 | c.1057C>A p.L353M | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV101184404; called by muse, mutect2, varscan2
- CEP135 | c.62A>T p.Y21F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99954686; called by muse, mutect2, varscan2
- CIB2 | c.346+2T>A p.X116_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99363385; called by muse, mutect2, varscan2
- CNKSR2 | c.2668G>T p.A890S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99669208; called by muse, mutect2, varscan2
- COL9A2 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV101028663; called by muse, mutect2, varscan2
- COMP | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV99721513; called by muse, mutect2
- CRTAC1 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as COSV100085857, COSV53997190; called by muse, mutect2, varscan2
- CYP46A1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV55896481; called by muse, mutect2
- CYSLTR1 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100964744, COSV64820725; called by muse, mutect2
- DAAM2 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); catalogued as rs375083979, COSV51303029, COSV51355669; called by muse, mutect2, varscan2
- DCAF8L1 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV101491416, COSV71595388; called by muse, mutect2
- DENND2B | c.1676C>T p.S559L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV58203163; called by muse, mutect2
- DNAH10 | c.7190A>T p.D2397V (on ENST00000409039; = p.D2336V on NM_207437.3) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV101292440; called by muse, mutect2, varscan2
- DUSP29 | c.476T>G p.L159R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100633372; called by muse, mutect2, varscan2
- EGR3 | c.983C>A p.T328K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100416235; called by muse, mutect2
- EIF3M | c.880T>G p.F294V | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100025089; called by muse, mutect2, varscan2
- ENTPD3 | c.1562C>G p.A521G | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV100088868; called by muse, mutect2, varscan2
- EPS8 | c.786G>T p.M262I | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99843431; called by muse, mutect2
- ERMP1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284682; called by muse, mutect2, varscan2
- FAM71B | c.1685C>A p.A562D | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100262197; called by muse, mutect2
- FAT3 | c.7162A>T p.N2388Y | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99968065; called by muse, mutect2, varscan2
- FCRL4 | c.413G>A p.W138* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99620115; called by muse, mutect2, varscan2
- FGF19 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99594395; called by muse, mutect2
- FLNA | c.1991G>T p.R664L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100774924; called by muse, mutect2, varscan2
- FLNC | c.6288C>A p.C2096* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100368422; called by muse, mutect2, varscan2
- FLT4 | c.2410G>T p.A804S | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99987923; called by muse, mutect2
- FLT4 | c.1328T>A p.L443H | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99987930; called by muse, mutect2
- FRMPD1 | c.296A>T p.Q99L | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100733594; called by muse, mutect2
- FSTL5 | c.978T>A p.Y326* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100058418; called by muse, mutect2, varscan2
- GFRA1 | c.1166C>A p.T389N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV100815874; called by muse, mutect2
- GINS3 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV100139355; called by muse, mutect2, varscan2
- GLRA2 | c.1036A>T p.K346* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV99491381; called by muse, mutect2, varscan2
- GPAT2 | c.1532T>G p.L511R | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100853324; called by muse, mutect2, varscan2
- GPRC6A | c.1034T>A p.L345* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV100114556; called by muse, mutect2, varscan2
- GTF3C4 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100936049; called by muse, mutect2, varscan2
- HCN2 | c.1034del p.R345Pfs*12 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as COSV52112128; called by mutect2, pindel, varscan2
- HIP1 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.146); catalogued as COSV100417859; called by muse, mutect2
- HLTF | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026846, COSV100026962; called by muse, varscan2
- HNRNPH1 | c.1162A>T p.S388C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV100270803; called by muse, mutect2, varscan2
- HOXA9 | c.263A>T p.H88L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as COSV100604459; called by muse, mutect2, varscan2
- IFNGR1 | c.1249A>T p.S417C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100880914; called by muse, mutect2
- IGKV1-5 | c.309T>A p.D103E | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749183875; called by muse, mutect2, varscan2
- IL1RAPL1 | c.864A>C p.K288N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100148577; called by muse, mutect2
- IRS4 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV100929633, COSV64535046; called by muse, mutect2
- KCTD3 | c.709A>C p.K237Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99379497; called by muse, mutect2, varscan2
- KIAA1109 | c.5218G>A p.E1740K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99167691; called by muse, mutect2, varscan2
- KLF15 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV99955286; called by muse, mutect2, varscan2
- LCTL | c.735C>G p.N245K | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100427264; called by muse, mutect2, varscan2
- LEF1 | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV99489842; called by muse, mutect2, varscan2
- LPA | c.2901G>C p.M967I | Missense Mutation (SNP) | VAF 109/688 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.682); catalogued as COSV100307460; called by muse, mutect2, varscan2
- LPAR5 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100321062; called by muse, mutect2, varscan2
- LRRC7 | c.3566G>T p.G1189V (on ENST00000651989 / NM_001370785.2; = p.G1156V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99225280; called by muse, mutect2, varscan2
- LRRC8B | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100446628; called by muse, mutect2, varscan2
- MAP3K15 | c.2486G>A p.G829D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100135186; called by muse, mutect2
- MBL2 | c.617C>A p.T206K | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV100906312, COSV100906374; called by muse, mutect2, varscan2
- MRGPRX2 | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100316790; called by muse, mutect2, varscan2
- MUC17 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 101/501 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1374858351, COSV100074282; called by muse, mutect2, varscan2
- MUC5AC | c.15657C>A p.D5219E | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.576); catalogued as COSV100611524; called by muse, mutect2
- MYH4 | c.3022C>A p.Q1008K | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV99701750; called by muse, mutect2, varscan2
- NDN | c.783T>G p.F261L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.079); catalogued as COSV100086576, COSV59359694; called by muse, mutect2
- NEIL2 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99462363; called by muse, mutect2, varscan2
- NFXL1 | c.1430A>G p.Q477R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV100216922; called by muse, mutect2, varscan2
- NLRP14 | c.1320C>A p.Y440* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as rs145713104, COSV100205217, COSV55071245; called by muse, mutect2, varscan2
- NMBR | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs201747486, COSV57803453; called by muse, varscan2
- NRROS | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.216); catalogued as COSV100145548; called by muse, mutect2
- NUTM2F | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99480258; called by muse, mutect2
- NUTM2F | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.382); catalogued as COSV99480260; called by muse, mutect2
- OBP2A | c.475A>T p.M159L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1362015748, COSV100535637; called by muse, mutect2, varscan2
- OPN5 | c.814T>C p.S272P | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99789935; called by muse, mutect2, varscan2
- OR10A7 | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.892); catalogued as COSV100406610; called by muse, mutect2, varscan2
- OR4A15 | c.901A>T p.S301C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV100124195, COSV59037467; called by muse, mutect2, varscan2
- OR4D11 | c.821C>A p.T274N | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV100506592; called by muse, mutect2, varscan2
- OR56A1 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.046); catalogued as COSV100360514; called by muse, mutect2, varscan2
- PAK3 | c.1301G>A p.R434Q (on ENST00000262836 / NM_001324328.2; = p.R419Q on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99457849; called by muse, mutect2
- PAPPA2 | c.1551G>T p.W517C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV100866880; called by muse, mutect2, varscan2
- PAQR9 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV100503872; called by muse, mutect2, varscan2
- PCDH11X | c.2308C>G p.L770V | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.816); catalogued as COSV100015924, COSV53441394, COSV53472899; called by muse, mutect2
- PCDH15 | c.298G>T p.G100* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as CM1310663, COSV100224269; called by muse, mutect2, varscan2
- PCDHA4 | c.1904G>T p.R635L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as COSV63543797; called by muse, mutect2, varscan2
- PPP1R10 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.359); catalogued as COSV100919903; called by muse, mutect2, varscan2
- PRDX4 | c.127A>G p.R43G | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.083); catalogued as COSV101026737; called by muse, mutect2, varscan2
- PRG4 | c.3452T>C p.V1151A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.104); catalogued as COSV100798262; called by muse, mutect2, varscan2
- PSG7 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 79/440 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101343294; called by muse, mutect2, varscan2
- RBP3 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs782753173; called by muse, mutect2
- RECK | c.656G>C p.R219T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV100937559; called by muse, mutect2
- REG3A | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as COSV59411520; called by muse, mutect2
- RNF148 | c.60G>T p.R20S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as rs1004993499, COSV100411672; called by muse, mutect2, varscan2
- RPL6 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs139449403; called by muse, mutect2, varscan2
- SBSN | c.1688C>T p.T563M (on ENST00000452271 / NM_001166034.2; = p.T220M on NM_198538.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772418905, COSV71733038; called by muse, mutect2, varscan2
- SCN10A | c.4315C>T p.Q1439* | Nonsense Mutation (SNP) | VAF 26/182 reads (14%) | catalogued as rs1268286686, COSV101479473; called by muse, mutect2, varscan2
- SEC14L5 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs202231927; called by muse, mutect2, varscan2
- SEL1L | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs2371800, COSV100378018; called by muse, mutect2
- SERINC2 | c.1240G>A p.E414K (on ENST00000373709 / NM_178865.5; = p.E418K on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.602); catalogued as rs1553135306, COSV101037031, COSV65489911; called by muse, mutect2, varscan2
- SH2B2 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100159500; called by muse, mutect2, varscan2
- SLC10A4 | c.921G>C p.M307I | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV99906946; called by muse, mutect2
- SLC18A3 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV100340510; called by muse, mutect2
- SLC26A8 | c.2740C>G p.P914A | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV100839549, COSV62888142; called by muse, mutect2, varscan2
- SLC27A1 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV99393503; called by muse, mutect2, varscan2
- SLC29A1 | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs149882143, COSV100505857; called by muse, mutect2, varscan2
- SLC35F6 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV100733687; called by muse, mutect2
- SLC4A3 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as COSV56093744, COSV56097408; called by muse, mutect2, varscan2
- SLC5A5 | c.1293C>A p.F431L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV99715217; called by muse, mutect2, varscan2
- SOGA3 | c.1950G>T p.Q650H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375131228; called by muse, mutect2, varscan2
- SPDYA | c.889A>G p.N297D | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV100066704; called by muse, mutect2, varscan2
- SPHKAP | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as COSV100764279, COSV60879334; called by muse, mutect2, varscan2
- SPIRE2 | c.258G>T p.M86I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV100988893; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | PolyPhen probably damaging (0.949); catalogued as COSV100084339; called by muse, mutect2, varscan2
- SYNE1 | c.1967A>T p.Q656L (on ENST00000367255 / NM_182961.4; = p.Q663L on NM_033071.3) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1312078, COSV99572267; called by muse, mutect2
- TAP2 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 18/140 reads (13%) | catalogued as COSV100886917; called by muse, mutect2, varscan2
- TENM4 | c.6445G>T p.G2149C | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99576619; called by muse, mutect2
- TIE1 | c.1708T>A p.L570M | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.183); catalogued as rs767238455, COSV65252061; called by muse, mutect2, varscan2
- TNFRSF21 | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as COSV99729978; called by muse, mutect2, varscan2
- TREM1 | c.654C>A p.S218R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99776253; called by muse, mutect2, varscan2
- TRIM16L | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV101192607, COSV67459242; called by muse, mutect2, varscan2
- TRIP12 | c.5678G>T p.S1893I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV99390662; called by muse, mutect2
- TRIP12 | c.3558A>T p.L1186F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV99390664; called by mutect2, varscan2
- TRIP12 | c.3557T>A p.L1186* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99390665; called by muse, varscan2
- TRIP12 | c.2580A>C p.R860S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99390666; called by muse, mutect2, varscan2
- TRPS1 | c.52G>T p.G18C (on ENST00000220888 / NM_001330599.2; = p.G31C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); catalogued as COSV55259068, COSV99629266; called by muse, mutect2, varscan2
- TTN | c.22874A>T p.K7625I (on ENST00000591111; = p.K6698I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | PolyPhen benign (0.173); catalogued as COSV100621189; called by muse, mutect2
- TTN | c.17006G>T p.S5669I (on ENST00000591111; = p.S4742I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/99 reads (12%) | PolyPhen possibly damaging (0.605); catalogued as COSV100615121; called by muse, mutect2, varscan2
- TTN | c.9078C>A p.N3026K (on ENST00000591111; = p.N2980K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | PolyPhen benign (0.121); catalogued as COSV100621190; called by muse, mutect2, varscan2
- UNC5D | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs1298267760, COSV54771476, COSV99777213; called by muse, mutect2, varscan2
- VGLL1 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV101034680, COSV65703155; called by muse, mutect2, varscan2
- WWC3 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV66508460; called by muse, mutect2
- ZBTB4 | c.649A>T p.R217W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as COSV100263570; called by muse, mutect2, varscan2
- ZC3H8 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as COSV99735585; called by muse, mutect2, varscan2
- ZFC3H1 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as rs907890636, COSV100350535, COSV57348359; called by muse, mutect2, varscan2
- ZNF263 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV99527028; called by muse, mutect2
- ZSCAN1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs376273314; called by muse, mutect2, varscan2
- AC245033.1 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- HKDC1 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGKV1-16 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PRLHR | c.183del p.L62* | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, varscan2
- RBM17 | c.530del p.P177Hfs*6 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel, varscan2
- RPL10L | c.201_203delinsAA p.A68Tfs*10 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by pindel, varscan2*
- CDH10 | c.2022C>A p.T674= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs760760327, COSV52586615; called by muse, mutect2, varscan2
- CELSR2 | c.7974C>T p.P2658= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as COSV99604381; called by muse, mutect2
- CSF3R | c.426C>T p.C142= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100118022; called by muse, mutect2, varscan2
- CSMD3 | c.6876C>A p.G2292= (on ENST00000297405 / NM_001363185.1; = p.G2188= on NM_052900.3) | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV52323842; called by muse, mutect2, varscan2
- DLG5 | c.4542G>T p.V1514= | Silent (SNP) | VAF 26/209 reads (12%) | catalogued as COSV100967665; called by muse, mutect2, varscan2
- FAM47C | c.1986G>C p.R662= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV100792725, COSV100792816; called by muse, mutect2, varscan2
- FOXC1 | c.396C>G p.L132= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV66515808; called by muse, mutect2
- FPR1 | c.342C>T p.F114= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV59050899; called by muse, mutect2, varscan2
- GLP2R | c.825C>T p.Y275= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs777796266, COSV99302257; called by muse, mutect2, varscan2
- H2BC12 | c.27C>T p.P9= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs147650678; called by mutect2, varscan2
- HECW2 | c.2643T>A p.A881= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV99648000; called by muse, mutect2, varscan2
- KLC2 | c.21G>T p.P7= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV100385169; called by muse, mutect2
- LRP12 | c.819C>T p.P273= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs112084544, COSV99408040; called by muse, mutect2, varscan2
- MAGEB6B | c.735G>T p.T245= | Silent (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- MMRN1 | c.1230C>T p.F410= | Silent (SNP) | VAF 25/187 reads (13%) | catalogued as COSV99307441; called by muse, mutect2, varscan2
- MON2 | c.6C>T p.S2= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as rs772578972, COSV99743054; called by muse, mutect2, varscan2
- NR0B1 | c.1062C>G p.S354= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100973555, COSV66764454; called by muse, mutect2, varscan2
- OR4D1 | c.666G>T p.L222= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99274217; called by muse, mutect2
- OR8H2 | c.801C>T p.S267= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV57944275; called by muse, mutect2
- PKM | c.957A>T p.R319= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100065035, COSV100065039; called by muse, mutect2, varscan2
- PLCH1 | c.3048A>G p.P1016= (on ENST00000340059 / NM_001130960.2; = p.P1008= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV100397550; called by muse, mutect2, varscan2
- PLEKHM1 | c.1851G>T p.L617= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV101378807; called by muse, mutect2, varscan2
- PSD4 | c.3057G>A p.S1019= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV99831297; called by muse, mutect2
- RASGEF1A | c.111C>T p.D37= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV65667362; called by muse, mutect2
- RASGRF2 | c.2676G>A p.G892= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV54122711, COSV99429788; called by muse, mutect2, varscan2
- REXO1 | c.723G>C p.S241= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV99402497; called by muse, mutect2, varscan2
- RFX4 | c.1317C>A p.I439= (on ENST00000392842 / NM_213594.3; = p.I345= on NM_032491.6) | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV99986107; called by muse, mutect2, varscan2
- RIMS2 | c.1971G>T p.V657= (on ENST00000666250 / NM_001348490.2; = p.V465= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99177460; called by muse, mutect2, varscan2
- RNASEL | c.1083C>G p.L361= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV62378318; called by muse, mutect2
- RYR2 | c.6237G>A p.E2079= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100771944; called by muse, mutect2, varscan2
- SCN7A | c.2958A>G p.K986= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV101313304; called by muse, mutect2
- SIM1 | c.1707A>G p.R569= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99492552; called by muse, mutect2, varscan2
- SLC25A43 | c.957C>A p.P319= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as COSV99474658; called by muse, mutect2
- SLC28A1 | c.360C>T p.L120= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV99723240; called by muse, mutect2
- SLC49A4 | c.954C>G p.G318= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as COSV99659175; called by muse, mutect2, varscan2
- SMU1 | c.768C>T p.A256= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs751836938, COSV101238556; called by muse, mutect2, varscan2
- TBX4 | c.654G>A p.V218= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as COSV99540468; called by muse, mutect2, varscan2
- TTLL7 | c.1329A>G p.R443= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs199619560, COSV53085446; called by muse, mutect2, varscan2
- UVSSA | c.735C>T p.P245= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV101104538; called by muse, mutect2, varscan2
- ZC4H2 | c.660G>T p.R220= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100565069, COSV62003602; called by muse, varscan2
- ZNF25 | c.222A>G p.P74= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100224702; called by muse, mutect2, varscan2
- CCDC33 | c.1291-11553C>A | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99173387; called by muse, mutect2, varscan2
- KNOP1P1 | n.169G>A | RNA (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- LUZP4 | c.*1T>C | 3'UTR (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100904862; called by muse, mutect2, varscan2
- PRKCB | c.1864-5237G>T | Intron (SNP) | VAF 4/51 reads (8%) | catalogued as COSV100334670, COSV57776094; called by muse, mutect2
- RPGR | c.2520+253C>G | Intron (SNP) | VAF 4/9 reads (44%) | catalogued as CM141737, COSV100140223; called by muse, mutect2
- THSD4 | c.1016-70350G>T | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- VNN3 | c.*51A>T | 3'UTR (SNP) | VAF 20/86 reads (23%) | catalogued as COSV99258481; called by muse, mutect2, varscan2
